Gene-level copy-number profile of tumor specimen ALCH-AEJU-TTP1-A from ALCHEMIST case ALCH-AEJU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.0 years (21,202 days).
Specimen ALCH-AEJU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8d44fe5f-c075-4ab8-b27c-9e57a5e04b67.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AEJU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/93b17616-1b40-4a32-8323-1e262bad2b3a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 259; copy number 2: 56,542; copy number 3: 1,562; copy number 5: 1; copy number 6: 2; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,432,204–120,434,052, 1 gene: PFN1P2.
- chr1:202,632,428–202,632,911, 1 gene (within-gene range 0–2): AC104463.1.
- chr3:2,088,933–2,089,211, 1 gene: RN7SKP144.
- chr4:183,037,665–183,040,119, 1 gene: CIBAR1P2.
- chr10:23,343,957–23,345,181, 1 gene (within-gene range 0–2): AL606469.1.
- chr15:25,180,497–25,215,622, 20 genes (within-gene range 0–2): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25.
- chr19:16,065,737–16,158,575, 7 genes: LINC01855, TPM4, AC008894.3, AC008894.1, RAB8A, AC008894.2, HSH2D.
- chr22:18,855,621–18,894,407, 3 genes (within-gene range 0–2): BCRP7, FAM230F, AC008103.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,414,483–43,479,534, 4 genes, copy number 5–8 (within-gene range 5–44): SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 259. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
